Gene-level copy-number profile of tumor specimen TCGA-AG-4021-01A from TCGA case TCGA-AG-4021, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 84.9 years (31,015 days).
Specimen TCGA-AG-4021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.fff3f669-702c-41c7-b8fc-56902dd04154.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-4021-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/75030f0d-dcf6-4870-9d33-c49159fe5d4b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 14,383; copy number 2: 42,680; copy number 3: 811; copy number 4: 1,534; copy number 6: 16; copy number 9: 233; copy number 11: 85; copy number 12: 33; copy number 17: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-4021-01A-01D-1732-01): tumor purity 0.81, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:142,286,917–142,317,546, 2 genes: RPL5P13, LSM3P4.
- chr18:63,586,989–64,423,601, 14 genes: SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 395 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,770,176–57,174,236, 302 genes, copy number 6–17 (broad region; genes not listed).
- chr13:26,254,104–30,810,645, 93 genes, copy number 11–17 (within-gene range 2–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,446. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
